Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADM, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADM-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : HCC on liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Open segmentectomy

Organs: Liver (13.0 x 7.0 x 6.5 cm, 218.5 gm)

Lesion: An ill-defined multinodular confluent lesion (3.0 x 2.7 x 4.0 cm)
and a small separated nodule (0.7 x 0.5 x 0.3 cm),
second small nodule (0.9 x 0.8 x 0.3 cm)

Resection margin: Not involved grossly

(safety margin of large mass: 3.0 cm, safety margin of small mass: 0.2 cm)

Satellite nodule: No

Remaining parenchyma: Cirrhotic

Gross photo: Present

Blocks

T1-5, TB, tumor mass x 6

L, NB, liver parenchyma x 2

RM, resection margin x 1

MS1-2, additional nodule-like lesions x 2

ICD O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0
JFS 5/20/14

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma (#3)

Histologic grade (Edmondson-Steiner grade for hepatocellular carcinoma)

The worst differentiation: III

The major differentiation: III

Histologic type: Trabecular and pseudoglandular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: No

Septum formation: Yes

Surgical resection margin invasion: No (safety margin-0.1 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: Unknown

Multicentric occurrence: Yes

NOT reported. Gross:

liver,ectomy,hepatocellular carcinoma

[page 2 of 2]
T56000, P10, M81703

DIAGNOSIS:

Liver, segment 5 and 6, segmentectomy:

Hepatocellular carcinoma, moderately differentiated

(Edmondson-Steiner grade 3/4)

Cirrhosis, micronodular

ADDITIONAL DIAGNOSIS

Liver, segment 5 and 6, segmentectomy:

Hepatocellular carcinoma, moderately differentiated (#3)

Suggestion :

Source: NCI Genomic Data Commons file a32e9034-c388-4c56-b37d-0668cda6a69e (TCGA-DD-AADM.36839A87-47E6-4E63-8683-A1549549AECE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).